Somatic mutation profile of tumor specimen TCGA-12-0656-01A (aliquot TCGA-12-0656-01A-03W-0348-08) from TCGA case TCGA-12-0656, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.9 years (17,865 days).
Specimen TCGA-12-0656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66edd7da-0972-4580-a7c3-a002dde74a8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0656-10A (Blood Derived Normal), aliquot TCGA-12-0656-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b47c841-0c15-4866-9c88-7935b4768f29

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 16, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 54/248 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 802/1167 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 387/687 reads (56%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs771018417, COSV51908221; called by muse, mutect2, varscan2
- ADAM22 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 486/1788 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV55982223; called by muse, mutect2, varscan2
- ANLN | c.479A>T p.D160V | Missense Mutation (SNP) | VAF 104/400 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56077657; called by muse, mutect2, varscan2
- CERS5 | c.1142A>T p.N381I | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV58189656; called by muse, mutect2, varscan2
- CLDN12 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 108/412 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs1252002472, COSV55307370; called by muse, mutect2, varscan2
- CNMD | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV65033505; called by muse, mutect2, varscan2
- ERAS | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as COSV54433064, COSV54433383; called by muse, mutect2, varscan2
- GLI3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 218/989 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.037); catalogued as rs965164354, COSV67891176; called by muse, mutect2, varscan2
- HEATR3 | c.1510+1G>A p.X504_splice | Splice Site (SNP) | VAF 16/29 reads (55%) | catalogued as rs1247821040, COSV99589800; called by muse, mutect2, varscan2
- ING5 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.729); catalogued as rs778176408, COSV57979277; called by muse, mutect2, varscan2
- INO80 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1466180067, COSV62739938; called by muse, varscan2
- KIF2B | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs181862662; called by muse, mutect2, varscan2
- LRP2 | c.6037C>T p.R2013C | Missense Mutation (SNP) | VAF 700/1789 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs747459560, COSV55561536; called by muse, mutect2, varscan2
- MYH10 | c.3283G>A p.A1095T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as rs753724964, COSV52599502; called by muse, mutect2, varscan2
- NF1 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 104/932 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1400902839, COSV62209052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.3311T>G p.L1104R | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as CM153413, COSV62209938; called by muse, mutect2, varscan2
- NPIPA1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.056); catalogued as rs774137205, COSV100047511, COSV60154015; called by muse, mutect2, varscan2
- OLFML3 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 107/140 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57436309; called by muse, mutect2, varscan2
- PCMTD2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV55059035; called by muse, mutect2
- PIWIL1 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55348805; called by muse, mutect2, varscan2
- PSMD12 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1363601696, COSV62065987; called by muse, mutect2, varscan2
- R3HDM1 | c.2150G>C p.G717A | Missense Mutation (SNP) | VAF 328/917 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV51527814; called by muse, mutect2, varscan2
- RPGR | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58833546; called by muse, mutect2, varscan2
- SLIT2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV56581203; called by muse, mutect2, varscan2
- TENT5D | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 385/1015 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57637671; called by muse, mutect2, varscan2
- TLN2 | c.4786C>T p.Q1596* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV60891913; called by muse, varscan2
- TTN | c.59903C>T p.T19968M (on ENST00000591111; = p.T12544M on NM_003319.4) | Missense Mutation (SNP) | VAF 102/264 reads (39%) | PolyPhen possibly damaging (0.903); catalogued as rs765913263, COSV100599053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 27/628 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99390356; called by muse, mutect2
- ZNF25 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 99/159 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56923201; called by muse, mutect2, varscan2
- ZNF641 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs373026137; called by muse, mutect2, varscan2
- DARS2 | c.1005_1006dup p.R336Lfs*5 | Frame Shift Ins (INS) | VAF 89/344 reads (26%) | called by mutect2, pindel, varscan2
- MYH6 | c.1328_1329del p.R443Hfs*32 | Frame Shift Del (DEL) | VAF 104/211 reads (49%) | called by pindel, varscan2
- ALKBH2 | c.426G>A p.R142= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as rs1448743952, COSV57448351; called by muse, mutect2
- BMP3 | c.235C>T p.L79= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99261445; called by muse, mutect2, varscan2
- BRAP | c.1320C>T p.N440= | Silent (SNP) | VAF 125/407 reads (31%) | catalogued as COSV59537406; called by muse, mutect2, varscan2
- CD163L1 | c.1032C>T p.S344= | Silent (SNP) | VAF 168/444 reads (38%) | catalogued as rs1464957571, COSV58019640; called by muse, mutect2, varscan2
- CNOT1 | c.3318C>G p.L1106= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV55319233; called by muse, mutect2, varscan2
- FBXO27 | c.630C>T p.D210= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs552069426, COSV53072729; called by muse, mutect2, varscan2
- FOXA2 | c.1308G>A p.S436= (on ENST00000377115 / NM_153675.3; = p.S442= on NM_021784.5) | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs938291131, COSV65796619; called by muse, mutect2, varscan2
- INTS3 | c.2680C>T p.L894= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99669757; called by muse, mutect2, varscan2
- PCDHB5 | c.186G>A p.R62= | Silent (SNP) | VAF 19/262 reads (7%) | catalogued as COSV50657683; called by muse, mutect2
- POLA1 | c.414C>T p.F138= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV100985117; called by muse, mutect2
- POLR1A | c.3777C>T p.I1259= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99807236; called by muse, varscan2
- SAMD4A | c.2118C>T p.H706= | Silent (SNP) | VAF 18/418 reads (4%) | catalogued as rs1169556154, COSV99200545; called by muse, mutect2
- SPATA31A1 | c.3936G>A p.K1312= | Silent (SNP) | VAF 116/374 reads (31%) | catalogued as COSV66533690; called by muse, mutect2, varscan2
- TKTL2 | c.12C>T p.N4= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs759652519, COSV54919941; called by muse, mutect2, varscan2
- TRHR | c.1038T>A p.A346= | Silent (SNP) | VAF 320/996 reads (32%) | catalogued as COSV61235284; called by muse, mutect2, varscan2
- TSHZ3 | c.1338C>T p.P446= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV99550865; called by muse, mutect2
- RNF217-AS1 | n.1652C>T | RNA (SNP) | VAF 141/262 reads (54%) | called by muse, mutect2, varscan2
